Gene-level copy-number profile of tumor specimen TCGA-09-2056-01B from TCGA case TCGA-09-2056, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 62.6 years (22,864 days).
Specimen TCGA-09-2056-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.794b6a48-f610-4711-8b1a-4736252c8bea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-2056-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/03e4f986-c8e6-418e-907d-10c07c634b78

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 21,343; copy number 2: 33,437; copy number 3: 4,718; copy number 4: 92; copy number 5: 170; copy number 7: 14; copy number 11: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-09-2056-01): tumor purity 0.89, ploidy 1.77, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 223 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,487,364–152,623,103, 119 genes, copy number 5 (broad region; genes not listed).
- chr12:23,529,504–24,562,544, 1 gene, copy number 11 (within-gene range 1–11): SOX5.
- chr12:24,212,421–26,833,194, 52 genes, copy number 7–11 (within-gene range 2–11): MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1.
- chr16:89,171,748–90,222,851, 51 genes, copy number 5: CDH15, SLC22A31, AC009113.1, ZNF778, AC009113.2, ANKRD11, AC137932.3, AC137932.1, AC137932.2, AC092120.1, AC092120.3, RNU6-430P, AC092120.2, SPG7, AC092123.1, RPL13, SNORD68, CPNE7, DPEP1, CHMP1A, SPATA33, AC010538.1, CDK10, LINC02166, SPATA2L, VPS9D1, VPS9D1-AS1, ZNF276, FANCA, SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.

Autosomal genes at a single copy (total copy number 1): 19,943. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
